Somatic mutation profile of tumor specimen MMRF_1031_1_BM_CD138pos (aliquot MMRF_1031_1_BM_CD138pos_T2_TSE61_K02456) from MMRF case MMRF_1031, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.3 years (22,760 days).
Specimen MMRF_1031_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60605501-98c2-4b59-9ae8-ea5ecd089d41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1031_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1031_1_PB_Whole_C1_TSE61_K02449; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bd610fa-e217-4307-9d88-367a6fcedc15

The open-access MAF lists 142 somatic variants for this specimen: 62 protein-altering or splice-affecting, 25 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, 3'UTR 35, Silent 25, 5'UTR 7, Intron 5, RNA 5, Nonsense Mutation 4, 3'Flank 3, Frame Shift Ins 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANK3 | c.2203C>T p.H735Y | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV99783347; called by muse, mutect2, varscan2
- ANKRD6 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs367690340; called by muse, mutect2, varscan2
- CCDC186 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.737); catalogued as COSV65162302; called by muse, mutect2, varscan2
- CLVS1 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as rs756911932, COSV100370014; called by mutect2, varscan2
- CRAMP1 | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs533832759; called by muse, mutect2, varscan2
- DOCK1 | c.615A>C p.Q205H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1030549055; called by muse, mutect2, varscan2
- GRIK5 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781816651, COSV53475581; called by muse, mutect2, varscan2
- GRM7 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs1029563007; called by muse, mutect2, varscan2
- KCNH5 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as COSV59760521; called by muse, mutect2, varscan2
- KIF2B | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52126846; called by muse, mutect2, varscan2
- LPAR2 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539775382; called by muse, mutect2, varscan2
- MGAT5B | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775745785; called by muse, mutect2, varscan2
- MYOCD | c.2624G>A p.S875N | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.15); catalogued as rs201316990; called by muse, mutect2, varscan2
- NLRP10 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV60783212; called by muse, mutect2, varscan2
- NOX5 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.778); catalogued as rs766116758, COSV52986788; called by muse, mutect2, varscan2
- OR5M11 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs778688024, COSV73141978; called by muse, mutect2, varscan2
- PCLO | c.8760G>A p.M2920I | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV61666223; called by muse, mutect2, varscan2
- PDYN | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV54101604; called by muse, mutect2, varscan2
- SEMA3A | c.1877A>G p.H626R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752800188; called by muse, mutect2, varscan2
- SLC32A1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54145571; called by muse, mutect2, varscan2
- TNRC18 | c.4189G>T p.E1397* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as COSV68168280; called by muse, mutect2, varscan2
- VWCE | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 60/84 reads (71%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs529893923, COSV57110678, COSV57111256; called by muse, mutect2, varscan2
- ZIM3 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV54142024, COSV54143836, COSV54146692; called by muse, mutect2, varscan2
- ADGRF5 | c.1281C>G p.Y427* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- AP3B2 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- APOBR | c.881C>A p.A294E | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ARRDC4 | c.731_733del p.T244del | In Frame Del (DEL) | VAF 23/104 reads (22%) | called by mutect2, pindel, varscan2
- CCDC168 | c.11267C>A p.P3756Q | Missense Mutation (SNP) | VAF 58/81 reads (72%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CDK11A | c.1768T>A p.W590R (on ENST00000378633 / NM_001313896.2; = p.W587R on NM_024011.4) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- CRYBG3 | c.7493A>T p.E2498V | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CSPG4 | c.6557C>T p.A2186V | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ELAPOR2 | c.3023C>T p.A1008V (on ENST00000450689 / NM_001142749.3; = p.A841V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- GDA | c.1112T>C p.L371P | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEATR1 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH6 | c.2788G>A p.A930T | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- KIF12 | c.923C>A p.P308Q (on ENST00000640217; = p.P170Q on NM_138424.1) | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF12 | c.922C>G p.P308A (on ENST00000640217; = p.P170A on NM_138424.1) | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL26 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- LRRC52 | c.298G>T p.V100F | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- LRRC7 | c.3101G>A p.R1034Q (on ENST00000651989 / NM_001370785.2; = p.R1001Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARCHF1 | c.43A>C p.I15L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED23 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- MINDY4 | c.1566G>C p.Q522H | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MOCS3 | c.173A>G p.D58G | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MUC16 | c.23477C>T p.A7826V | Missense Mutation (SNP) | VAF 40/291 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYO15A | c.7523C>T p.P2508L | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- NLGN1 | c.1700C>A p.P567H | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PCDHB14 | c.1148G>A p.C383Y | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLAAT1 | c.185G>A p.C62Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R36 | c.386T>G p.L129R | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- R3HDM2 | c.269T>G p.F90C | Missense Mutation (SNP) | VAF 66/68 reads (97%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- REN | c.134G>T p.S45I | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RHPN1 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.338); called by muse, varscan2
- RNPC3 | c.117_118insA p.A40Sfs*2 | Frame Shift Ins (INS) | VAF 19/57 reads (33%) | called by mutect2, pindel, varscan2
- ROBO1 | c.1778C>A p.S593Y | Missense Mutation (SNP) | VAF 53/86 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RORC | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- SF3B3 | c.2017G>A p.V673M | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- TCF7L2 | c.1425C>A p.N475K (on ENST00000355995 / NM_001367943.1; = p.N452K on NM_030756.5) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VCAN | c.1823C>A p.P608H | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- WASL | c.582A>C p.K194N | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF493 | c.334T>G p.Y112D | Missense Mutation (SNP) | VAF 179/664 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACP4 | c.1231C>T p.L411= | Silent (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- CCDC114 | c.546C>T p.Y182= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs762832505, COSV59556573; called by muse, mutect2, varscan2
- CEP295 | c.2721G>A p.L907= | Silent (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
- DAPK1 | c.3492C>T p.D1164= | Silent (SNP) | VAF 35/177 reads (20%) | catalogued as rs776403573; called by muse, mutect2, varscan2
- DROSHA | c.2424C>G p.P808= | Silent (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- EFCAB1 | c.426T>C p.P142= | Silent (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- FAT3 | c.1257C>T p.Y419= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV53170798, COSV99965747; called by muse, mutect2, varscan2
- FER1L5 | c.3027G>A p.A1009= (on ENST00000623019; = p.A1016= on NM_001293083.2) | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1057152943; called by muse, mutect2, varscan2
- INPP5E | c.1650G>A p.R550= | Silent (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- KCNH5 | c.2352C>G p.L784= | Silent (SNP) | VAF 48/99 reads (48%) | called by muse, mutect2, varscan2
- KLHL26 | c.1222C>T p.L408= | Silent (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- LIPJ | c.1005T>G p.T335= | Silent (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- MYBPC2 | c.660G>C p.G220= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as rs757877926; called by muse, mutect2, varscan2
- MYOM1 | c.4800G>A p.P1600= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs368423483; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHAC1 | c.1011C>T p.A337= | Silent (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.10056A>T p.V3352= | Silent (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- PRLHR | c.555G>A p.A185= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV53305127; called by muse, mutect2, varscan2
- RD3 | c.549C>A p.S183= | Silent (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- SHROOM3 | c.1176C>T p.Y392= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as rs761601802, CM155602; called by muse, mutect2, varscan2
- SIPA1L1 | c.1953C>G p.L651= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- SPTBN1 | c.6975C>T p.R2325= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs779397892, COSV63341704; called by muse, mutect2, varscan2
- TTC21B | c.495G>A p.L165= | Silent (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- VASH1 | c.243G>T p.V81= | Silent (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- ZDHHC18 | c.756C>T p.F252= | Silent (SNP) | VAF 61/145 reads (42%) | catalogued as rs766302100; called by muse, mutect2, varscan2
- ZNF366 | c.1935C>T p.P645= | Silent (SNP) | VAF 41/140 reads (29%) | catalogued as rs148082239; called by muse, mutect2, varscan2
- ABCG1 | c.*330C>T | 3'UTR (SNP) | VAF 28/67 reads (42%) | catalogued as rs1002889091; called by muse, mutect2, varscan2
- ABHD13 | c.*96G>T | 3'UTR (SNP) | VAF 63/83 reads (76%) | called by muse, mutect2, varscan2
- AC090983.2 | n.1064A>G | RNA (SNP) | VAF 26/96 reads (27%) | catalogued as rs888921055; called by muse, mutect2, varscan2
- ADAMTS5 | c.*3051G>T | 3'UTR (SNP) | VAF 36/114 reads (32%) | called by muse, mutect2, varscan2
- ADAMTS9 | c.*771T>G | 3'UTR (SNP) | VAF 47/142 reads (33%) | called by muse, mutect2, varscan2
- BCRP4 | n.171-541C>T | Intron (SNP) | VAF 57/94 reads (61%) | called by muse, mutect2, varscan2
- BIN2 | c.*167T>C | 3'UTR (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- C6 | c.-14G>A | 5'UTR (SNP) | VAF 30/46 reads (65%) | catalogued as COSV99666237; called by muse, mutect2, varscan2
- CCSER1 | c.2094+23163G>T | Intron (SNP) | VAF 43/126 reads (34%) | catalogued as rs267600297, COSV61411328; called by muse, mutect2, varscan2
- COL26A1 | c.*552C>T | 3'UTR (SNP) | VAF 19/50 reads (38%) | catalogued as rs897831463; called by muse, mutect2, varscan2
- DLG2 | c.*4223T>G | 3'UTR (SNP) | VAF 39/104 reads (38%) | called by muse, mutect2, varscan2
- DPF3 | c.871+3288T>C | Intron (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- EFR3A | c.*2275A>C | 3'UTR (SNP) | VAF 72/153 reads (47%) | called by muse, mutect2, varscan2
- EMX2OS | n.2096C>G | RNA (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- EPB41L5 | c.*3106A>G | 3'UTR (SNP) | VAF 41/80 reads (51%) | called by muse, mutect2, varscan2
- FAM27E5 | n.475C>T | RNA (SNP) | VAF 89/249 reads (36%) | catalogued as rs780838963; called by muse, mutect2, varscan2
- FGFR1 | c.936+425C>T | Intron (SNP) | VAF 31/75 reads (41%) | catalogued as rs1289700429; called by muse, mutect2, varscan2
- FOXB1 | c.-31G>A | 5'UTR (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2
- FOXRED1 | c.*342C>G | 3'UTR (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- GIPR | c.633+145G>T | Intron (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- GORASP1 | c.*521C>T | 3'UTR (SNP) | VAF 32/108 reads (30%) | catalogued as rs745337596; called by muse, mutect2, varscan2
- GRIN2A | c.*1822G>A | 3'UTR (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- HAPLN2 | c.*169G>C | 3'UTR (SNP) | VAF 12/15 reads (80%) | called by muse, mutect2, varscan2
- HMX2 | c.*455T>C | 3'UTR (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- IL19 | chr1:206842897 G>T | 3'Flank (SNP) | VAF 36/116 reads (31%) | called by muse, mutect2, varscan2
- INSYN2A | c.*1077del | 3'UTR (DEL) | VAF 45/126 reads (36%) | called by mutect2, pindel, varscan2
- KIAA1549 | c.*4446C>T | 3'UTR (SNP) | VAF 29/88 reads (33%) | catalogued as rs1419287317; called by muse, mutect2, varscan2
- LRAT | c.*2814C>T | 3'UTR (SNP) | VAF 40/109 reads (37%) | called by muse, mutect2, varscan2
- LRRC10B | c.*314G>T | 3'UTR (SNP) | VAF 36/139 reads (26%) | called by muse, mutect2, varscan2
- LRRC47 | c.*535G>A | 3'UTR (SNP) | VAF 46/101 reads (46%) | catalogued as rs564771217; called by muse, mutect2, varscan2
- MAFB | c.*275A>T | 3'UTR (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- MIDEAS | c.-386G>A | 5'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20396540 A>C | 3'Flank (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2, varscan2
- PABPC4L | c.*540A>C | 3'UTR (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- PAPPA | c.*3388A>G | 3'UTR (SNP) | VAF 52/193 reads (27%) | called by muse, mutect2, varscan2
- PCLO | c.*750A>G | 3'UTR (SNP) | VAF 82/133 reads (62%) | called by muse, mutect2, varscan2
- PDPR | c.*1672T>G | 3'UTR (SNP) | VAF 48/334 reads (14%) | called by muse, mutect2, varscan2
- REST | c.-67T>G | 5'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- RLBP1 | c.*259T>G | 3'UTR (SNP) | VAF 107/196 reads (55%) | called by muse, mutect2, varscan2
- RUBCN | c.*2439C>T | 3'UTR (SNP) | VAF 23/63 reads (37%) | catalogued as rs537923205; called by muse, mutect2, varscan2
- SDK1 | c.*1753C>T | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- SHLD2P1 | n.2345A>G | RNA (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- SLC35F5 | c.-125G>A | 5'UTR (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2
- SNPH | c.*2958C>T | 3'UTR (SNP) | VAF 38/90 reads (42%) | called by muse, mutect2, varscan2
- SOCS6 | c.*2087C>T | 3'UTR (SNP) | VAF 29/97 reads (30%) | called by muse, mutect2, varscan2
- TAGLN3 | c.-6C>A | 5'UTR (SNP) | VAF 76/128 reads (59%) | called by muse, mutect2, varscan2
- TCEA1 | c.*993T>A | 3'UTR (SNP) | VAF 74/167 reads (44%) | called by muse, mutect2, varscan2
- TMEM45A | c.-171C>T | 5'UTR (SNP) | VAF 29/91 reads (32%) | catalogued as rs1273647545; called by muse, mutect2, varscan2
- TNRC6C | c.*2261C>T | 3'UTR (SNP) | VAF 50/116 reads (43%) | catalogued as rs1174133151; called by muse, mutect2, varscan2
- TRIQK | chr8:92883869 A>T | 3'Flank (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- TSIX | n.1544T>G | RNA (SNP) | VAF 55/64 reads (86%) | called by muse, mutect2, varscan2
- UNC13A | c.*4343C>T | 3'UTR (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
- VWA1 | c.*826G>T | 3'UTR (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- WLS | c.*352G>T | 3'UTR (SNP) | VAF 8/23 reads (35%) | catalogued as rs1368790691; called by muse, mutect2, varscan2
- ZNF695 | c.*226G>T | 3'UTR (SNP) | VAF 44/167 reads (26%) | called by muse, mutect2, varscan2
